Somatic mutation profile of tumor specimen ALCH-AE8X-TTP1-A (aliquot ALCH-AE8X-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AE8X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.6 years (25,067 days).
Specimen ALCH-AE8X-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2ddc18b-b2a7-4040-a30a-79cc733cd2a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE8X-NB1-A (Blood Derived Normal), aliquot ALCH-AE8X-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c6dc39-4970-42e6-9ceb-2936f9899c96

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 3, Intron 2, 5'UTR 2, 3'Flank 1, In Frame Del 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 112/1331 reads (8%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- CCNQ | c.573del p.I191Mfs*155 | Frame Shift Del (DEL) | VAF 31/254 reads (12%) | catalogued as COSV52344718; called by mutect2, pindel, varscan2
- IQSEC3 | c.1415G>A p.G472D (on ENST00000538872 / NM_001170738.2; = p.G169D on NM_015232.1) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as rs782599497; called by muse, mutect2
- PDHA2 | c.419G>T p.R140I | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV54777907; called by muse, mutect2, varscan2
- PSME4 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66364279; called by muse, mutect2
- RARA | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205678, COSV54190879; ClinVar: drug response; called by muse, varscan2
- SLC1A4 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1355893948; called by muse, mutect2
- UNC13A | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1357397448; called by muse, mutect2
- ZNF80 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs370641478, COSV57361764; called by muse, mutect2
- ADAM20 | c.1990A>T p.K664* | Nonsense Mutation (SNP) | VAF 22/265 reads (8%) | called by muse, mutect2
- ANKRD12 | c.5461A>C p.K1821Q | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC22 | c.881C>A p.T294K | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- CSF3R | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 21/223 reads (9%) | called by muse, mutect2
- DENND4A | c.5144A>G p.Y1715C | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); called by muse, mutect2
- MCL1 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- METTL25 | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFGE8 | c.893A>T p.E298V | Missense Mutation (SNP) | VAF 33/664 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2
- MTDH | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 38/554 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ORC6 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 65/666 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- RIPK3 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2
- RTF1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- RTF1 | c.620A>G p.E207G | Missense Mutation (SNP) | VAF 17/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SF3B1 | c.2693A>T p.Y898F | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TET3 | c.3933C>A p.S1311R | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- VWA5A | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF479 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 52/599 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.95); called by muse, mutect2
- IGLL5 | c.495A>G p.K165= | Silent (SNP) | VAF 89/1370 reads (6%) | catalogued as rs535701345; called by muse, mutect2
- NCAPH2 | c.327G>C p.G109= | Silent (SNP) | VAF 35/577 reads (6%) | called by muse, mutect2
- P4HB | c.585A>G p.K195= | Silent (SNP) | VAF 31/420 reads (7%) | called by muse, mutect2
- PCDHA12 | c.2091C>T p.N697= | Silent (SNP) | VAF 73/682 reads (11%) | catalogued as COSV56495744; called by muse, mutect2, varscan2
- PNMA3 | c.1026A>G p.P342= | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- RALGDS | c.1465C>T p.L489= | Silent (SNP) | VAF 34/785 reads (4%) | called by muse, mutect2
- RTL1 | c.2484C>T p.I828= | Silent (SNP) | VAF 20/568 reads (4%) | called by muse, mutect2
- SPTB | c.3618G>T p.G1206= | Silent (SNP) | VAF 88/705 reads (12%) | called by mutect2, varscan2
- GABBR1 | c.-1+165G>T | Intron (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2, varscan2
- LAPTM4B | c.-129C>T | 5'UTR (SNP) | VAF 76/1000 reads (8%) | called by muse, mutect2
- PGPEP1 | c.-7T>A | 5'UTR (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- SYNPO | chr5:150656454 C>A | 3'Flank (SNP) | VAF 37/266 reads (14%) | called by muse, mutect2, varscan2
- TMCC2 | c.748-12544A>G | Intron (SNP) | VAF 49/449 reads (11%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439462 T>A | 5'Flank (SNP) | VAF 53/697 reads (8%) | called by muse, mutect2
